Gene-level copy-number profile of tumor specimen TCGA-ND-A4WF-01A from TCGA case TCGA-ND-A4WF, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Fundus uteri; FIGO stage: Stage IIIA; Age at diagnosis: 77.7 years (28,398 days).
Specimen TCGA-ND-A4WF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.ab338973-88c0-4eed-92ca-884909d3ea23.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ND-A4WF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/17194610-0db0-4708-a3fa-aa6f7be1d60e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 561; copy number 2: 21,239; copy number 3: 27,828; copy number 4: 7,593; copy number 5: 1,662; copy number 6: 356; copy number 7: 173; copy number 8: 100; copy number 9: 21; copy number 10: 9; copy number 12: 8; copy number 14: 67; copy number 15: 33; copy number 20: 52; copy number 23: 57; copy number 24: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ND-A4WF-01A-11D-A28Q-01): tumor purity 0.95, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:43,219,849–43,596,046, 6 genes (within-gene range 0–1): AC010883.3, ZFP36L2, LINC01126, AC010883.1, THADA, RNU6-958P.
- chr3:116,850,277–116,965,227, 4 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P.
- chr4:181,064,089–181,159,149, 1 gene (within-gene range 0–1): LINC00290.
- chr4:181,522,666–182,145,249, 7 genes (within-gene range 0–1): AC093840.1, AC093840.2, AC084741.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1.
- chr8:3,700,492–4,329,027, 2 genes: RNA5SP251, AC027251.1.
- chr11:86,153,227–86,278,813, 5 genes: RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 538 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:48,050,659–48,497,736, 15 genes, copy number 7: LINC02794, AL356289.1, CYP46A4P, SKINT1L, AL356289.2, AL109659.1, SLC5A9, AL109659.2, AL109659.3, SPATA6, PPP1R8P1, RNU6-723P, AL356968.2, RNU4-61P, AL356968.1.
- chr1:48,552,991–48,558,106, 1 gene, copy number 7: AL391844.1.
- chr3:176,068,042–181,836,880, 87 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:6,346,465–6,622,771, 1 gene, copy number 7 (within-gene range 3–7): LY86-AS1.
- chr6:6,450,356–6,995,727, 13 genes, copy number 7: AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1.
- chr6:11,414,636–11,709,960, 8 genes, copy number 10: AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1.
- chr6:11,722,547–11,731,923, 1 gene, copy number 10 (within-gene range 4–10): AL022724.3.
- chr6:125,577,545–126,258,355, 10 genes, copy number 7 (within-gene range 4–7): AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5.
- chr7:129,756,266–130,216,844, 16 genes, copy number 7: RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1.
- chr8:127,578,473–128,564,679, 18 genes, copy number 24 (within-gene range 3–24): AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr10:77,587,049–77,587,159, 1 gene, copy number 7: RNA5SP321.
- chr12:5,226,196–5,521,536, 6 genes, copy number 7: LINC02443, AC006206.2, AC006206.1, AC007848.2, AC007848.1, NTF3.
- chr12:9,228,533–9,845,007, 32 genes, copy number 8: A2MP1, MIR1244-3, PTMAP4, LINC00987, AC010175.1, AC009533.1, SNORA75, AC009533.2, AC009533.3, LINC02367, AC009533.4, AC141557.1, AC141557.2, DDX12P, SNORA75, AC092821.3, AC092821.1, AC092821.2, KLRB1, RNU6-700P, GOT2P3, AC010186.4, AC010186.1, AC010186.2, AC010186.3, CLEC2D, NPM1P7, LINC02390, CLECL1, CD69, GCNAP1, KLRF1.
- chr12:16,188,485–16,277,685, 1 gene, copy number 9: SLC15A5.
- chr12:16,661,766–32,100,735, 266 genes, copy number 8–23 (broad region; genes not listed).
- chr12:69,901,918–71,032,083, 14 genes, copy number 9 (within-gene range 2–9): PRANCR, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1.
- chr12:117,889,454–118,062,430, 5 genes, copy number 9: AC084291.1, RFC5, AC131159.2, WSB2, AC131159.1.
- chr12:118,066,398–118,066,725, 1 gene, copy number 9: AC131238.1.
- chr19:30,219,666–31,787,255, 19 genes, copy number 8: AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P.
- chr20:31,377,164–31,834,689, 23 genes, copy number 7 (within-gene range 3–7): DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2.

Autosomal genes at a single copy (total copy number 1): 556. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
